Somatic mutation profile of tumor specimen MBCProject_4813_T1_WES (aliquot MBCProject_4813_T1_WES_1) from CMI case MBCProject_4813, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 56.7 years (20,715 days).
Specimen MBCProject_4813_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b9f85ad0-a26f-4666-9f03-bd6282ae984d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_4813_SALIVA (Saliva), aliquot MBCProject_4813_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/92f5985e-911e-4137-abb6-0cb50ee49a2c

The open-access MAF lists 42 somatic variants for this specimen: 24 protein-altering or splice-affecting, 14 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 14, Nonsense Mutation 3, Intron 2, 3'UTR 1, Frame Shift Del 1, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADA | c.659C>T p.S220L | Missense Mutation (SNP) | VAF 53/287 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.232); catalogued as rs747167602, COSV100596140; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGAP23 | c.3053G>A p.R1018Q | Missense Mutation (SNP) | VAF 11/218 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs1435456900; called by muse, mutect2
- ARNTL2 | c.1666-1G>C p.X556_splice | Splice Site (SNP) | VAF 7/48 reads (15%) | catalogued as COSV99668167; called by muse, varscan2
- GTF3C1 | c.3892C>T p.R1298W | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs549367031; called by muse, mutect2, varscan2
- LSAMP | c.530G>A p.G177E | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as COSV61287953; called by muse, mutect2, varscan2
- OR51G1 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as rs143904984, COSV58970464; called by muse, mutect2, varscan2
- PLCE1 | c.2414G>A p.R805Q | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs757088793, COSV53335733, COSV99593711; called by muse, mutect2, varscan2
- RCOR2 | c.1561C>T p.P521S | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.055); catalogued as rs980705434; called by muse, mutect2
- TIGD4 | c.1200G>T p.L400F | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100427912; called by mutect2, varscan2
- TNKS1BP1 | c.211C>A p.P71T | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs774815208, COSV64102807; called by muse, mutect2, varscan2
- TRPM2 | c.398C>T p.T133M | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as rs145770865; called by muse, mutect2, varscan2
- CARD14 | c.2062G>T p.E688* | Nonsense Mutation (SNP) | VAF 22/123 reads (18%) | called by muse, mutect2, varscan2
- CEP170 | c.377C>T p.S126L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.035); called by mutect2, varscan2
- DMXL1 | c.3605G>T p.S1202I | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- EML1 | c.1559G>A p.G520D | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ERC1 | c.847C>T p.L283F | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FBXO11 | c.374del p.S125* (on ENST00000403359 / NM_001190274.2; = p.S41* on NM_025133.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 47/129 reads (36%) | called by mutect2, pindel, varscan2
- GPSM2 | c.1633G>A p.D545N | Missense Mutation (SNP) | VAF 16/233 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.076); called by muse, mutect2
- H3C6 | c.302T>A p.L101* | Nonsense Mutation (SNP) | VAF 39/255 reads (15%) | called by muse, mutect2, varscan2
- HMCN1 | c.4222C>T p.Q1408* | Nonsense Mutation (SNP) | VAF 23/182 reads (13%) | called by muse, mutect2, varscan2
- LRRTM4 | c.1459G>T p.D487Y | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PSMD3 | c.1175A>G p.Y392C | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- SPTA1 | c.3280A>T p.M1094L | Missense Mutation (SNP) | VAF 24/184 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- VWF | c.1345C>T p.P449S | Missense Mutation (SNP) | VAF 32/274 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ABCG1 | c.1584G>A p.P528= | Silent (SNP) | VAF 21/195 reads (11%) | catalogued as rs374817134, COSV100494537; called by muse, mutect2, varscan2
- ATP2B2 | c.1080C>T p.D360= (on ENST00000352432; = p.D326= on NM_001683.5) | Silent (SNP) | VAF 45/129 reads (35%) | catalogued as rs763566134, COSV59492692; called by muse, mutect2, varscan2
- CHRNA2 | c.744C>T p.C248= | Silent (SNP) | VAF 35/214 reads (16%) | catalogued as rs1256906114, COSV53558447; called by muse, mutect2, varscan2
- GUCY2C | c.2451G>A p.P817= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs376557537; called by mutect2, varscan2
- LRRIQ1 | c.4920G>A p.G1640= | Silent (SNP) | VAF 49/99 reads (49%) | called by muse, mutect2, varscan2
- MLKL | c.102C>T p.R34= | Silent (SNP) | VAF 7/98 reads (7%) | catalogued as rs1396363746; called by muse, mutect2
- NCKAP5L | c.3516C>T p.R1172= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as rs375263255; called by muse, mutect2, varscan2
- PDIA4 | c.642C>G p.P214= | Silent (SNP) | VAF 33/181 reads (18%) | catalogued as rs567468691; called by muse, mutect2, varscan2
- RPS6KA2 | c.636C>T p.H212= | Silent (SNP) | VAF 22/270 reads (8%) | catalogued as rs200188704, COSV55815908; called by muse, mutect2
- SERPINF2 | c.78C>T p.S26= | Silent (SNP) | VAF 20/134 reads (15%) | catalogued as rs764369234; ClinVar: likely benign; called by muse, mutect2, varscan2
- SMG8 | c.2490G>A p.A830= | Silent (SNP) | VAF 16/156 reads (10%) | catalogued as rs201839267; called by muse, mutect2, varscan2
- SRSF2 | c.486G>A p.K162= | Silent (SNP) | VAF 12/88 reads (14%) | catalogued as rs1417460228; called by muse, mutect2, varscan2
- VAV1 | c.1812C>T p.Y604= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as rs373953397; called by muse, mutect2, varscan2
- ZFHX4 | c.7635G>T p.P2545= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as COSV50970890; called by muse, mutect2, varscan2
- ABI3BP | c.1577-17593C>G | Intron (SNP) | VAF 13/134 reads (10%) | called by muse, mutect2, varscan2
- ATP8B2 | c.464+17G>A | Intron (SNP) | VAF 35/184 reads (19%) | catalogued as COSV59248957; called by muse, mutect2, varscan2
- CHCHD2 | c.-5C>G | 5'UTR (SNP) | VAF 13/114 reads (11%) | called by muse, mutect2, varscan2
- MYBPHL | c.*20G>A | 3'UTR (SNP) | VAF 7/67 reads (10%) | catalogued as rs1557760905; called by muse, mutect2, varscan2
